Gene-level copy-number profile of tumor specimen HTMCP-03-06-02267-01A from CGCI case HTMCP-03-06-02267, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 38.6 years (14,107 days).
Specimen HTMCP-03-06-02267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3be390de-f8fd-4538-887b-75ea8f57bcb0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02267-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/e8a98519-8150-41bc-a5a8-94b251e9b822

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 783; copy number 3: 9,395; copy number 4: 22,487; copy number 5: 9,437; copy number 6: 15,134; copy number 7: 624; copy number 8: 318; copy number 9: 30; copy number 11: 40; copy number 15: 74; copy number 16: 5; copy number 19: 4; copy number 21: 10; copy number 22: 4; copy number 25: 2; copy number 27: 3; copy number 28: 1; copy number 31: 17; copy number 36: 3; copy number 44: 22.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 215 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:113,924,000–114,153,880, 5 genes, copy number 16: HIPK1-AS1, HIPK1, OLFML3, AL591742.1, SYT6.
- chr1:114,582,848–116,478,842, 40 genes, copy number 15: DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA.
- chr1:118,883,046–119,853,748, 34 genes, copy number 15: TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9.
- chr7:38,239,580–38,249,572, 1 gene, copy number 9: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 9: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:114,922,359–118,951,259, 66 genes, copy number 19–44 (broad region; genes not listed).
- chr8:140,505,813–141,195,808, 13 genes, copy number 9: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr9:120,855,651–120,929,173, 2 genes, copy number 9: PHF19, TRAF1.
- chr14:22,147,995–22,483,069, 39 genes, copy number 11: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
